Surgical pathology report (de-identified scan), TCGA case TCGA-2H-A9GO, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Erasmus MC, specimen TCGA-2H-A9GO-01A (Primary Tumor).

Pathology Report

Coded sample ID:

Date of tumor procurement:

Date of report:

Histologic diagnosis: poor differentiated adenocarcinoma located in Barrett-epithelium

Anatomic site with laterality: distal esophagus

Tumor size: 4.5x2.5 cm

Lymph node status: 13 lymph nodes, of which 9 contain tumor

Any comments or amendments: irradical resection

ICD-O-3

Adenocarcinoma NOS 8140/3
Site: Esophagus, distal third C15.5
W 1/29/14

Source: NCI Genomic Data Commons file 0d32a4f4-88ff-494a-838b-3e04d6742aac (TCGA-2H-A9GO.EBB6A6B5-F330-4A0D-B99D-2B42A12A68B0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).